Surgical pathology report (de-identified scan), TCGA case TCGA-RB-A7B8, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Emory University, specimen TCGA-RB-A7B8-01A (Primary Tumor).

[page 1 of 5]
Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status:
Document Title: Histology
Performed By:
Verified By:
Encounter info:

* Final Report *

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Acc #:

DOB:

Gender:

F

(Age:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. BILE DUCT MARGIN, EXCISION (A1FS):
- NEGATIVE FOR CARCINOMA.

B. PANCREATIC NECK MARGIN, EXCISION (B1FS):
- NEGATIVE FOR CARCINOMA.

C. RETROPERITONEAL MARGIN, EXCISION (C1FS):
- NEGATIVE FOR CARCINOMA.

D. LYMPH NODE, HEPATIC ARTERY, EXCISION:
- ONE LYMPH NODE WITH CAUTERY ARTIFACT, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

E. PANCREAS AND DUODENUM, PANCREATICODUODENECTOMY:
- INVASIVE ADENOCARCINOMA, MODERATELY DIFFERENTIATED, PANCREATOBILIARY TYPE WITH FOCAL MICROPAPILLARY COMPONENT, (2.3 X 2.2 X 2.0 CM).

ICD-O-3

Adenocarcinoma w/ mixed
subtypes (pancreatobiliary & micropapillary)
8255/3

Site Pancreas head
25.0

JA 8/22/13

Printed by:

Printed on:

[page 2 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

- CARCINOMA INVOLVES THE PERIPANCREATIC SOFT TISSUE.
- PERINEURAL INVASION IS PRESENT.
- LYMPHOVASCULAR INVASION IS NOT IDENTIFIED.
- CARCINOMA EXTENDS TO THE RETROPERITONEAL EDGE; REFER TO SPECIMEN 'C' FOR STATUS OF RETROPERITONEAL MARGIN.
- COMMON BILE DUCT EDGE AND PANCREATIC NECK EDGE ARE NEGATIVE FOR CARCINOMA; REFER TO PARTS 'A' AND 'B' FOR STATUS OF BILE DUCT AND PANCREATIC NECK MARGINS, RESPECTIVELY.
- PROXIMAL AND DISTAL DUODENAL MARGINS ARE NEGATIVE FOR CARCINOMA.
- EIGHT OF TWENTY-THREE LYMPH NODES ARE POSITIVE FOR METASTATIC CARCINOMA (8/23).
- SEE SYNOPTIC REPORT AND COMMENT.

Comment

There is a cystic component to the tumor (approximately 20% grossly) which is not clearly an intraductal papillary mucinous neoplasm (IPMN). The differential diagnosis includes colonization of a retention cyst or large duct by carcinoma versus IPMN replaced by carcinoma.

Some of the positive lymph nodes appear to be positive by direct extension of the tumor.

The micropapillary component accounts for approximately 10% of the tumor.

Selected slides from this case have been reviewed at our daily _____ with
concurring with the diagnosis.

Synoptic Worksheet

E. Whipple:

Specimen:	Head of pancreas ✓ Duodenum Common bile duct
Procedure:	Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy
Tumor Site:	Pancreatic head
Tumor Size:	Greatest dimension: 2.3 cm Additional dimension: 2.2 cm Additional dimension: 2.0 cm
Histologic Type:	Ductal adenocarcinoma ✓
Histologic Grade:	G2: Moderately differentiated
Microscopic Tumor Extension:	Tumor invades peripancreatic soft tissues
Margins:	Margins uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 1 mm

Printed by:
Printed on:

[page 3 of 5]
Anat Path Reports

* Final Report *

Treatment Effect:	Margin: Retroperitoneal
Lymph-Vascular Invasion:	Margins uninvolved by carcinoma in situ
Perineural Invasion:	No prior treatment
TNM Descriptors:	Not identified
Primary Tumor (pT):	Present
Regional Lymph Nodes (pN):	Not applicable
Distant Metastasis (pM):	pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
Additional Pathologic Findings:	pN1: Regional lymph node metastasis
	Number of lymph nodes examined: 8
	Number of lymph nodes involved: 24
	Not applicable
	None identified

Clinical History

Pancreatic head mass. Whipple.

Specimen(s) Received

- A: Bile duct margin
- B: Pancreatic neck margin
- C: Retroperitoneal margin
- D: Hepatic artery node
- E: Whipple

Gross Description

Five specimens are received, each labeled with the patient's name and medical record number.

Specimen A is received fresh for intraoperative consultation, identified with the patient's name and medical record number and designated as "bile duct margin." The specimen consists of luminal soft tissue measuring 0.8 x 0.5 x 0.2 cm. The entire specimen is submitted for frozen section diagnosis and the contents of the cryoblock are transferred to cassette "A1FS." Dictated by

Specimen B is received fresh for intraoperative consultation, identified with the patient's name and medical record number and designated as "pancreatic neck margin." The specimen consists of a fragment of soft tissue measuring 0.5 x 0.3 x 0.1 cm. The entire specimen is submitted for frozen section diagnosis and the contents of the cryoblock are transferred to cassette "B1FS." Dictated by

Specimen C is received fresh for intraoperative consultation, identified with the patient's name and medical record number and designated as "retroperitoneal margin." The specimen consists of a fragment of soft tissue measuring 1.5 x 1.1 x 0.1 cm. The entire specimen is submitted for frozen section diagnosis and the contents of the cryoblock are transferred to cassette "C1FS." Dictated by

Specimen D is received in formalin and is labeled "hepatic artery node." It consists of two fragments of soft tissue measuring in

Printed by:
Printed on:

[page 4 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

egarding

Anat Path Reports

* Final Report *

aggredate 12 x 0.6 x 0.2 cm. The specimen is submitted entirely, wrapped in lens paper in cassette "D1." Dictated by

Specimen E is received fresh and is labeled "Whipple." It consists of a pancreaticoduodenectomy specimen with duodenum measuring 19.5 cm in length and 5.5 cm in circumference and pancreatic head measuring 4.5 cm anterior/posterior, 5.4 cm superior-to-inferior and 5.0 cm from duodenal edge to neck edge. The stomach and gallbladder are not present. The common bile duct is dilated and measures 2.9 cm in length and 0.6 cm in diameter. The pancreatic duct measures 3.0 cm in length and up to 0.2 cm in diameter. The two ducts open to different ampullae through separate orifices. The accessory ampulla measures 0.5 x 0.4 cm, does not communicate with the common bile duct nor the cystic duct, and is 1.0 cm from the proximal duodenal margin. There is a mass located predominantly in the pancreatic head that has both solid (80%) and cystic components (20%). The mass is tan-white with well-defined borders and measures 2.3 x 2.2 x 2.0 cm. Areas of necrosis are not identified. There are no polypoid or soft friable papillary areas. The mass does not involve the ampulla. The mass abuts the common bile duct and invasion cannot be grossly ruled out. The mass grossly involves the pancreatic duct causing constriction at 1.0 cm from the ductal edge. The mass does not involve the duodenum and is grossly confined to the pancreatic head. The mass is located 1.0 cm from the pancreatic neck edge and abuts and possibly involves the retroperitoneal edge and vascular bed. The mass abuts the free posterior lateral surface and is 0.8 cm from the free anterior surface. The accessory ampulla is uninvolved by the mass. A representative section of the mass as well as uninvolved duodenum is submitted to The specimen is inked as follows: vascular bed-blue, retroperitoneal edge-black, accessory ampulla-green, serosal surface-blue. Representative sections are submitted as stated below.

CASSETTE SUMMARY:

E1:	Common bile duct edge, shaved and en face
E2:	Pancreatic neck edge, shaved and en face
E3:	Representative vascular bed, perpendicular
E4, E5:	Retroperitoneal edge, perpendicular
E6:	Common bile duct lymph node
E7:	Superior head lymph nodes
E8, E9:	Anterior pancreaticoduodenal lymph nodes
E10, E11:	Anterior pancreatic lymph nodes
E12:	Inferior pancreatic head lymph nodes
E13:	Posterior pancreaticoduodenal lymph nodes
E14, E15:	Posterior pancreatic lymph nodes
E16:	Proximal duodenal margin, shaved
E17:	Distal duodenal margin, shaved
E18:	Accessory ampulla, shaved
E19:	Pancreatic duct, common bile duct, ampulla and mass (anterior)
E20:	Mass to pancreatic duct, common bile duct, duodenum and normal pancreas
E21:	Cystic area within mass to common bile duct and possibly pancreatic duct with invasion (anterior)
E22:	Mass center (anterior half)
E23:	Mass and common bile duct (posterior half)
E24:	Tumor to normal (anterior half)
E25:	Normal pancreas (anterior half)
E26, E27:	Additional mass (posterior half)
E28:	Duodenum, representative

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Intraoperative Consult Diagnosis

A1FS: BILE DUCT MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

on

in at out at

B1FS: PANCREATIC NECK MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

on

in at out at

C1FS: RETROPERITONEAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

on

in at out at

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Source: NCI Genomic Data Commons file 605dcd1e-94cf-483b-b67e-590673a643ca (TCGA-RB-A7B8.F63EAC42-1415-4F1F-B647-C9D61A2EB8C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).